Gene-level copy-number profile of tumor specimen ALCH-AFAV-TTP1-A from ALCHEMIST case ALCH-AFAV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,463 days).
Specimen ALCH-AFAV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aad5803f-8fc3-413a-ab3f-b668e426aa39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFAV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/7522c8d2-b5dd-4b31-b5e0-d1b2993510d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 240; copy number 2: 58,053; copy number 3: 11; copy number 5: 4; copy number 6: 3; copy number 7: 2; copy number 10: 3; copy number 12: 4; copy number 15: 3; copy number 20: 1; copy number 22: 1; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:243,049,782–243,056,394, 2 genes (within-gene range 0–2): CICP21, AL606534.4.
- chr2:44,932,320–44,946,071, 9 genes: AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr9:94,603,133–94,640,249, 1 gene: FBP1.
- chr10:63,658,074–63,658,521, 1 gene: AC022387.1.
- chr10:133,430,394–133,431,318, 1 gene: OR6L2P.
- chr14:99,500,190–99,604,207, 3 genes (within-gene range 0–2): CCDC85C, AL110504.1, Y_RNA.
- chr15:25,169,337–25,241,827, 40 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr17:81,976,807–82,098,294, 11 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr19:35,030,470–35,066,571, 2 genes (within-gene range 0–2): SCN1B, HPN.
- chr20:62,804,835–62,814,000, 1 gene (within-gene range 0–5): OGFR.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.
- chr22:23,059,415–23,164,350, 5 genes: RSPH14, GNAZ, Metazoa_SRP, U7, RAB36.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,427,790–27,442,259, 1 gene, copy number 6: NRBP1.
- chr10:133,420,666–133,424,572, 1 gene, copy number 22 (within-gene range 1–22): SPRN.
- chr16:16,541,217–16,541,847, 1 gene, copy number 5: AC136619.2.
- chr20:62,796,473–62,805,587, 2 genes, copy number 5 (within-gene range 0–5): MRGBP, OGFR-AS1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 10–20: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 12 (within-gene range 2–12): GATD3A.
- chr21:44,172,169–44,262,216, 8 genes, copy number 5–15: AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 12 (within-gene range 2–12): DGCR6, AC007326.4, PRODH.
- chr22:21,466,423–21,471,269, 1 gene, copy number 25: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
